TARGET case TARGET-40-0A4I4A — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b5916008-64f0-5077-9ac1-d0b477aa5487

Demographics
Sex at birth: female; Race: white; Age at index: 21 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 21.2 years (7,748 days); Year of diagnosis: 2008; Metastasis at diagnosis: No Metastasis; Days to last follow up: 1,583 days (4.3 years).
   Pathology details: Necrosis percent: 50.
   Treatment given: Protocol identifier: IHRT.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Methotrexate.
   Treatment given: Therapeutic agents: Platinum.

Follow-up (1 entry)
- Days to follow up: 1,583 days (4.3 years); Event-free: no event (relapse, second malignancy or death) recorded through day 1,583; Year of follow up: 2013.

Biospecimens (2 samples)
- Sample TARGET-40-0A4I4A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-0A4I4A-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 1583
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Therapy: Adria/Plat/MTX
